TCGA case TCGA-06-0240 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Henry Ford Hospital. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/a0700d6d-df7b-4327-8738-97b8ad08fd4c

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 57 years; Vital status: Dead; Days to death: 621 days (1.7 years).

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 57.3 years (20,937 days); Year of diagnosis: 2007; Method of diagnosis: Surgical Resection; Prior treatment: No.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 34 days; Days to treatment end: 65 days; Treatment dose: 6,000 cGy; Number of fractions: 30; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Days to treatment start: 34 days; Days to treatment end: 65 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cilengitide + Temozolomide; Days to treatment start: 36 days; Days to treatment end: 320 days.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Bevacizumab; Days to treatment start: 337 days; Days to treatment end: 589 days (1.6 years).
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Irinotecan; Days to treatment start: 337 days; Days to treatment end: 407 days (1.1 years).
   Treatment given: Treatment type: Radiation Therapy, NOS; Days to treatment start: 420 days (1.1 years); Days to treatment end: 432 days (1.2 years); Treatment dose: 3,600 cGy; Number of fractions: 6; Treatment anatomic sites: Locoregional Site.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Days to treatment start: 435 days (1.2 years); Days to treatment end: 511 days (1.4 years).
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Days to treatment start: 547 days (1.5 years); Days to treatment end: 589 days (1.6 years).

Follow-up (2 entries)
- Days to follow up: 621 days (1.7 years); Disease response: With Tumor.
- Karnofsky performance status: 90; Timepoint: Preoperative.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-06-0240-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 2; Intermediate dimension: 0.9; Shortest dimension: 0.9.
  Slide TCGA-06-0240-01A-01-BS1: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 10; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 100.
  Slide TCGA-06-0240-01A-02-BS2: Section location: Top; Percent tumor nuclei: 0; Percent necrosis: 0.
- Sample TCGA-06-0240-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Glioblastoma Multiforme (GBM); History lgg diagnosis of brain tissue: No; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection.

GDC annotations on this case (curator notes; quoted as recorded):
- Tumor class but appears normal on portion TCGA-06-0240-01A-02: Dx slide resembles normal tissue.
- Tumor class but appears normal on portion TCGA-06-0240-01A-03: Dx slide resembles normal tissue.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 621 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 621 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 621 days.
